Gene-level copy-number profile of tumor specimen TCGA-37-3789-01A from TCGA case TCGA-37-3789, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.1 years (23,782 days).
Specimen TCGA-37-3789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.37eec241-9093-412e-8826-ad3287fb76d7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-37-3789-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b59c3c1-add5-4b7a-8ee1-5c3a07b6b6fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 14,282; copy number 2: 36,818; copy number 3: 7,146; copy number 4: 553; copy number 5: 652; copy number 6: 97; copy number 7: 71; copy number 8: 60; copy number 9: 30; copy number 10: 62; copy number 12: 18; copy number 13: 6; copy number 14: 11; copy number 15: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-37-3789-01A-01D-0978-01): tumor purity 0.62, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,314,110–59,314,800, 1 gene: AC008833.1.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,013 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:177,816,865–198,222,513, 463 genes, copy number 5 (broad region; genes not listed).
- chr4:71,062,667–77,611,834, 116 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr7:52,493,152–55,862,755, 57 genes, copy number 7–15: AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr7:85,381,118–94,431,227, 119 genes, copy number 5–6 (within-gene range 5–8) (broad region; genes not listed).
- chr7:98,291,650–99,207,506, 15 genes, copy number 5–9: BAIAP2L1, AC093799.1, RPS3AP26, PPIAP82, AC074121.1, NPTX2, RNU6-393P, TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7.
- chr18:47,390–5,004,537, 101 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr18:10,666,483–11,149,569, 1 gene, copy number 7 (within-gene range 4–7): PIEZO2.
- chr18:10,724,619–11,929,476, 28 genes, copy number 7: KIAA0895LP1, MIR6788, AP005120.1, AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3.
- chr18:21,981,121–28,824,826, 112 genes, copy number 5–14 (within-gene range 2–14) (broad region; genes not listed).
- chr21:17,894,193–17,894,485, 1 gene, copy number 5: RPL37P3.

Autosomal genes at a single copy (total copy number 1): 11,895. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
